Surgical pathology report (de-identified scan), TCGA case TCGA-63-A5MB, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Ontario Institute for Cancer Research, specimen TCGA-63-A5MB-01A (Primary Tumor).

Sample Number

Sample Type TUMOUR

Diagnosis	Squamous Cell Carcinoma, Not Otherwise Specified (NOS)
Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	
Type of Procedure	RESECT
Site of Tissue/Primary (Histology)	Left upper lobe
Tumour Size (cm)	3
Histology	Squamous carcinoma
Grade/Differentiation	II
Pathological T	T2,NOS
Pathological N	N0
Clinical M	M0
VALCSG Stage	
Histology Comments	

Sample Number

Sample Type BUFFY

Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	

ICD O-3

Carcinoma, Squamous cell NOS

Site @ Lung, upper lobe

2/11/13

Criteria	W 2/7/13	Yes	No

Source: NCI Genomic Data Commons file 1c215205-0b3d-430b-b009-782334625892 (TCGA-63-A5MB.D830087F-913A-4E59-9EC4-A230E613B0DF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).